Somatic mutation profile of tumor specimen 0DTLGM from CCDI case PBCJSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.2 years (5,926 days).
Specimen 0DTLGM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1a75b07-43aa-4045-9538-8fb11790e8b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTLGF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c1414b1-872f-4843-b090-75216cc8f34a

The open-access MAF lists 23 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 4, 5'UTR 2, 3'UTR 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMKMT | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 232/916 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.225); catalogued as rs202168145, COSV65923867; called by muse, varscan2
- CST5 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 187/593 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100489739; called by muse, varscan2
- ELAVL2 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 86/628 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99805615; called by muse, varscan2
- PNPLA4 | c.631-1G>C p.X211_splice | Splice Site (SNP) | VAF 128/442 reads (29%) | catalogued as rs1180562594; called by muse, varscan2
- SCN8A | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 140/1182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1241368717; called by muse, varscan2
- FLYWCH1 | c.1151C>A p.T384N (on ENST00000253928 / NM_001308068.2; = p.T383N on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, varscan2
- LAMTOR1 | c.387G>T p.L129F | Missense Mutation (SNP) | VAF 158/490 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); called by muse, varscan2
- MOXD1 | c.1677G>T p.S559= | Splice Region (SNP) | VAF 97/753 reads (13%) | called by muse, varscan2
- TET3 | c.4382C>G p.S1461C | Missense Mutation (SNP) | VAF 97/782 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, varscan2
- UBXN11 | c.224T>C p.L75P (on ENST00000374221 / NM_183008.2; = p.L42P on NM_145345.2) | Missense Mutation (SNP) | VAF 113/652 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, varscan2
- ACOX2 | c.1293G>A p.S431= | Silent (SNP) | VAF 88/485 reads (18%) | catalogued as rs772915511; called by muse, varscan2
- MYG1 | c.1125C>A p.I375= | Silent (SNP) | VAF 119/754 reads (16%) | called by muse, varscan2
- SSX5 | c.339C>T p.P113= (on ENST00000347757 / NM_175723.1; = p.P154= on NM_021015.4) | Silent (SNP) | VAF 188/610 reads (31%) | catalogued as rs782359113; called by muse, varscan2
- ZNF219 | c.51G>A p.P17= | Silent (SNP) | VAF 164/1006 reads (16%) | catalogued as rs1434398512; called by muse, varscan2
- ZSWIM9 | c.1830G>A p.R610= | Silent (SNP) | VAF 28/199 reads (14%) | called by muse, varscan2
- ADAM15 | c.1917+55T>A | Intron (SNP) | VAF 126/465 reads (27%) | called by muse, varscan2
- AGFG1 | c.*34A>T | 3'UTR (SNP) | VAF 84/580 reads (14%) | called by muse, varscan2
- CD34 | c.973-64C>T | Intron (SNP) | VAF 42/276 reads (15%) | catalogued as rs1426903777; called by muse, varscan2
- DRG2 | c.376+71T>C | Intron (SNP) | VAF 36/200 reads (18%) | called by muse, varscan2
- PTPRO | c.3410+100T>A | Intron (SNP) | VAF 20/107 reads (19%) | called by muse, varscan2
- RGS8 | c.-115T>C | 5'UTR (SNP) | VAF 108/959 reads (11%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/268 reads (10%) | called by muse, varscan2
- TFR2 | c.*25G>A | 3'UTR (SNP) | VAF 48/256 reads (19%) | catalogued as rs1179410148, COSV99774727; called by muse, varscan2
